TCGA case TCGA-ZC-AAAH — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Mannheim. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3cc2d49b-a3a6-4f55-a355-68cbe84f4056

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Germany; Age at index: 52 years; Vital status: Alive.

Diagnoses (2)
1. Thymoma, type B2, malignant (the primary disease): ICD-O-3 morphology code: 8584/3; ICD-10 code: C38.1; Tissue or organ of origin: Anterior mediastinum; Site of resection or biopsy: Anterior mediastinum; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,146 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIb; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 497 days (1.4 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Thymoma, type B2, malignant), site: Mediastinum, NOS. Age at diagnosis: 52.9 years (19,312 days); Days to diagnosis: 166 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 166 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Mediastinum, NOS; Days to recurrence: 166 days.
- Days to follow up: 198 days; Disease response: Tumor Free.
- Days to follow up: 497 days (1.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 162 cm; BMI: 26.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZC-AAAH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 1,170 mg.
  Slide TCGA-ZC-AAAH-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ZC-AAAH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZC-AAAH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Stage record: Masaoka stage: IIb.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B2.
- Primary pathology: Method initial path diagnosis: Median Sternectomy; History myasthenia gravis: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 497 days; disease-specific survival: no event (censored), 497 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 166 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZC-AAAH-01A-11D-A427-01): tumor purity 0.25, ploidy 2, whole-genome doublings 0.
